Somatic mutation profile of tumor specimen TCGA-F2-6880-01A (aliquot TCGA-F2-6880-01A-11D-2154-08) from TCGA case TCGA-F2-6880, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 70.7 years (25,809 days).
Specimen TCGA-F2-6880-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecc38f70-2df3-44d4-b462-3b4d2c4d5020.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F2-6880-10A (Blood Derived Normal), aliquot TCGA-F2-6880-10A-01D-2154-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7abfac4-5b74-4596-abfc-ededee58b491

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIR2DS4 | c.105A>T p.P35= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs544475193; called by muse, mutect2, varscan2
